Gene-level copy-number profile of specimen HCM-CSHL-0377-C18-85A from HCMI case HCM-CSHL-0377-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 69.7 years (25,463 days).
Specimen HCM-CSHL-0377-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c5f98d43-cabf-40cf-bc87-5aee81fa284b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0377-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,705 have no estimate.
https://portal.gdc.cancer.gov/files/babd17a5-a5a0-4030-aed3-cad5f18808ce

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,003; copy number 2: 55,880; copy number 3: 35.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 148. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
